TARGET case TARGET-30-PALIIN — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/4f7aaa75-432c-5e97-be0a-8f7c1521eaf0

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 3 years; Vital status: Dead; Days to death: 1,395 days (3.8 years).

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; ICD-10 code: C80.0; Tissue or organ of origin: Unknown primary site; Classification of tumor: primary; Age at diagnosis: 3.5 years (1,279 days); Year of diagnosis: 2002; Days to last follow up: 1,395 days (3.8 years); Cog neuroblastoma risk group: High Risk; Inpc grade: Undifferentiated or Poorly Differentiated; INSS stage: Stage 4; Mitosis karyorrhexis index: High.
   Pathology details: Necrosis percent: 5; Percent tumor nuclei: 95.
   Treatment given: Protocol identifier: ANBL00B1.
   Treatment given: Protocol identifier: A3973.

Follow-up (4 entries)
- Days to follow up: 684 days (1.9 years); Progression or recurrence anatomic site: Intrathoracic lymph nodes; Days to first event: 684 days (1.9 years); First event: Relapse.
- Days to follow up: 684 days (1.9 years); Progression or recurrence anatomic site: Lymph nodes of multiple regions.
- Days to follow up: 684 days (1.9 years); Progression or recurrence anatomic site: Lymph nodes of head, face and neck.
- Days to follow up: 1,395 days (3.8 years); Year of follow up: 2005.

Molecular and laboratory tests
- MYCN amplification: Not Amplified.
- Test: Abnormal, NOS; Ploidy: Hyperdiploid.

Biospecimens (3 samples)
- Samples TARGET-30-PALIIN-01A, TARGET-30-PALIIN-01B (2 with the same recorded description): Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-30-PALIIN-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_NBL_ClinicalData_Discovery_20230523.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 1395
- Protocol: ANBL00B1, A3973
- Ploidy: Hyperdiploid (DI>1)
- Ploidy Value: 1.2
- Histology: Unfavorable
- ICDO: C80.9
- Percent Necrosis: 5
- Percent Tumor v/s Stroma: 90/10
- Site of Relapse: Other, specify: Lymph nodes-neck, mediastinal and paraspinal
